TARGET case TARGET-10-PALETF — Acute Lymphoblastic Leukemia - Phase I (TARGET-ALL-P1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e157a7f-8fa3-5b23-bee5-252dc9121df8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Dead; Days to death: 768 days (2.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.6 years (2,786 days); Year of diagnosis: 2001; Days to last follow up: 768 days (2.1 years).
   Treatment given: Protocol identifier: P9906.

Follow-up (2 entries)
- Days to follow up: 650 days (1.8 years); Days to first event: 650 days (1.8 years); First event: Relapse.
- Days to follow up: 768 days (2.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2003.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 106 ×10³/µL.
- Day 8: Bone Marrow blast count 3%; Minimal Residual Disease (Flow Cytometry) 0.1%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.0351%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Sample TARGET-10-PALETF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-10-PALETF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PALETF-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_I_20230727.xlsx:
- Overall Survival Time in Days: 768
- WBC at Diagnosis: 105.7
- CNS Status at Diagnosis: CNS 1
- MRD Day 8: 0.1
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.035057471
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 3
- BMA Blasts Day 29: 0
- Karyotype: 47,XX,+10[3]/46,XX,+10,-21[7]/46,XX[8]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: None of above
